Somatic mutation profile of tumor specimen TCGA-XQ-A8TB-01A (aliquot TCGA-XQ-A8TB-01A-11D-A364-08) from TCGA case TCGA-XQ-A8TB, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.4 years (24,623 days).
Specimen TCGA-XQ-A8TB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7aeecb71-ff78-4f9b-a316-9e5592067c75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XQ-A8TB-10A (Blood Derived Normal), aliquot TCGA-XQ-A8TB-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dbfe7f7-ea08-4148-b521-a5b3375a1009

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 16, Silent 8, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRTAC1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs767665227, COSV53997213; called by muse, mutect2, varscan2
- CSDC2 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.666); catalogued as rs1374373828, COSV53449628; called by muse, mutect2, varscan2
- ETV3L | c.827G>A p.S276N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV101485570; called by muse, mutect2, varscan2
- EVC2 | c.3742C>T p.P1248S | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100185669; called by muse, mutect2
- FBXO16 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100672248; called by muse, mutect2, varscan2
- HHEX | c.705A>C p.Q235H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV99262936; called by muse, mutect2, varscan2
- LRRTM1 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV99702258; called by muse, mutect2, varscan2
- MARK2 | c.1751G>A p.R584Q (on ENST00000402010 / NM_001039469.2; = p.R529Q on NM_004954.5) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV100158401; called by muse, mutect2, varscan2
- MTDH | c.1095G>T p.Q365H | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100292486; called by muse, mutect2, varscan2
- NEK8 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs752331372, COSV99261739; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFKBID | c.703C>T p.R235W (on ENST00000396901; = p.R387W on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs750159123, COSV100573205; called by muse, mutect2, varscan2
- OR51M1 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100150200; called by muse, mutect2, varscan2
- SLIT3 | c.4364G>A p.R1455Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs61735416, COSV60590880; called by muse, mutect2, varscan2
- SOCS5 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs377674278; called by muse, mutect2, varscan2
- TNRC18 | c.7082C>T p.P2361L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); catalogued as rs1184978954, COSV60310236; called by muse, mutect2, varscan2
- VWA3B | c.2071C>A p.L691M | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101345997; called by muse, mutect2, varscan2
- MICAL3 | c.102_110del p.E34_C36del | In Frame Del (DEL) | VAF 14/162 reads (9%) | called by mutect2, pindel
- PDCD11 | c.4619del p.N1540Mfs*4 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- COL6A3 | c.9147C>T p.L3049= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs183247300; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- CXCL1 | c.195C>T p.P65= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as rs779431090, COSV101203925; called by muse, mutect2, varscan2
- DIO3 | c.114C>T p.L38= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100832093; called by muse, mutect2, varscan2
- LGSN | c.435C>T p.S145= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs137949367; called by muse, mutect2, varscan2
- NOS1 | c.4143C>T p.D1381= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs750230730, COSV100500123; called by muse, mutect2, varscan2
- PEG3 | c.3279C>T p.D1093= | Silent (SNP) | VAF 49/112 reads (44%) | catalogued as COSV99688384; called by muse, mutect2, varscan2
- RAB15 | c.315C>T p.D105= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs781215341, COSV99962070; called by muse, mutect2, varscan2
- SRRM4 | c.585G>A p.S195= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs769309951, COSV57430869; called by muse, mutect2, varscan2
